Somatic mutation profile of tumor specimen TCGA-AB-2918-03A (aliquot TCGA-AB-2918-03A-01W-0745-08) from TCGA case TCGA-AB-2918, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.1 years (17,198 days).
Specimen TCGA-AB-2918-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c33aea0e-bc89-45c4-aa04-74a51a44a1c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2918-11A (Solid Tissue Normal), aliquot TCGA-AB-2918-11A-01W-0761-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2447c91d-c799-4a31-98bb-a9a52dd4396b

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC004922.1 | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as COSV53556835; called by muse, mutect2
- NBEAL1 | c.8080A>G p.K2694E | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV101355601; called by muse, varscan2
